Surgical pathology report (de-identified scan), TCGA case TCGA-VT-A80G, project TCGA-SARC (Sarcoma), tissue source site Vanderbilt, specimen TCGA-VT-A80G-01A (Primary Tumor).

[page 1 of 5]
YOM

Final Report

ICD O-3
Sarcoma, undifferentiated,
pleomorphic (8805/3)
(8802/3) Code to highest 8805/3
Site @ Buttock 49.5
W1/17/14

DIAGNOSIS:

- 1) SOFT TISSUE, PROXIMAL MARGIN, RIGHT BUTTOCK: NEGATIVE FOR MALIGNANCY.
- 2) SOFT TISSUE, PROXIMAL NERVE MARGIN, RIGHT BUTTOCK, EXCISION: POSITIVE FOR SARCOMA.
- 3-6) SOFT TISSUE, 3 O'CLOCK, 6 O'CLOCK, 9 O'CLOCK, AND 12 O'CLOCK MARGINS, EXCISIONS: NEGATIVE FOR MALIGNANCY.
- 7) SOFT TISSUE AND SKIN, RIGHT BUTTOCK MASS, EXCISION: UNDIFFERENTIATED PLEOMORPHIC SARCOMA, 20 CM IN GREATEST DIMENSION, MARGINS NEGATIVE FOR SARCOMA.

Soft Tissue Tumors Summary of Findings

Procedure: Radical resection

Tumor Site: Right buttock soft tissue

Tumor Size: 20.0 x 16.0 x 14.0 cm

Macroscopic Extent of Tumor: Deep, subfascial

Histologic Type (World Health Organization classification of soft tissue

tumors): undifferentiated pleomorphic sarcoma

Mitotic Rate: 17/10 high-power fields (HPF)

(1 HPF x 400 = 0.1734 mm²; X40 objective; most proliferative area)

Necrosis (macroscopic or microscopic): Present (Extent: 10%)

Histologic Grade (French Federation of Cancer Centers Sarcoma Group [FNCLCC]): Grade 3

Margins:

Margins negative for sarcoma

Distance of sarcoma from closest margin: 0.2 cm (inferior margin, gross assessment, specimen 7)

Other close margins (less than 2.0 cm) margin(s): 0.3 cm from the posterior and superior margin, 0.4 cm from the anterior margin,

0.6 cm

from the lateral margin, 1.0 cm from the medial margin

Residual Tumor Status: R0, No residual tumor

Lymph-Vascular Invasion: Not identified

AJCC/UICC Pathologic Staging (pTNM), 7th edition: Stage III

Primary Tumor (pT): pT2b, Tumor more than 5 cm in greatest

[page 2 of 5]
dimension,
deep tumor
Regional Lymph Nodes (pN): pNX, Regional lymph nodes cannot be
assessed
Distant Metastasis (pM): Not applicable

Ancillary Studies

Immunohistochemistry, Cytogenetics and Molecular Pathology: see
reports on biopsy specimen
Pre-resection Treatment: No therapy

CLINICAL DATA

Clinical Features: Right buttock high grade UPS.
Clinical Diagnosis: Undifferentiated
pleomorphic sarcoma.

Operator:

Operation: Right buttock mass resection

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1) Proximal margin-right buttock; 2)
Proximal nerve margin-right buttock, 3) 3
o'clock margin, right buttock, 4) 6
o'clock margin-right buttock , 5) 9
o'clock margin-right buttock, 6) 12
o'clock margin-right buttocks, 7) right
buttock mass

INSTRUCTIONS TO PATHOLOGIST: Frozen.

GROSS DESCRIPTION:

1) SOURCE: Proximal Margin Right Buttock

The specimen is received fresh for frozen in a container labeled with the patient's name and MR number and "proximal margin right buttock" and consists of a single irregular fragment of soft, dark-pink tissue with dimensions of 1.3 x 0.9 x 0.6 cm. The specimen is submitted entirely for frozen section evaluation. The frozen section control is submitted in cassette 1A, 1/1.

2) SOURCE: Proximal Nerve Margin Right Buttock

The specimen is received fresh for frozen in a container labeled with the patient's name and MR number and "proximal nerve margin-right buttock" and consists of 2 irregular fragments of soft, dark pink tissue with aggregate dimensions of 1.1 x 0.9 x 0.4 cm. The specimen is submitted entirely

[page 3 of 5]
for
frozen section evaluation. The frozen section control is submitted in
cassette 2A, 2/1.

3) SOURCE: 3 o'clock Margin

Received fresh in a container labeled with the patient's name, medical
record number, and "3 o'clock margin" is a single deep red soft tissue
fragment consistent with skeletal muscle measuring 1.4 x 0.7 x 0.5 cm.
The
entire specimen is submitted.
Summary of sections: 3AFSC, 1/1.

4) SOURCE: 6 o'clock Margin

Received fresh in a container labeled with the patient's name, medical
record number, and "6 o'clock margin" is a single deep red soft tissue
fragment consistent with skeletal muscle measuring 1.2 x 0.8 x 0.3 cm.
The
entire specimen is submitted.
Summary of sections: 4AFSC, 1/1.

5) SOURCE: 9 o'clock Margin

Received fresh for frozen labeled "9 o'clock margin" consists of an
irregular fragment of yellow-tan fatty tissue measuring 1.0 x 1.0 x 0.4
cm,
submitted entirely as frozen section residual, 5AFSC.

6) SOURCE: 12 o'clock Margin

The 12 o'clock margin consists of an irregular fragment of yellow-tan
fatty
tissue measuring 1.0 x 0.9 x 0.4 cm, submitted entirely as frozen
section
residual, 6AFSC, 1/1.

7) SOURCE: Right Buttock Mass

The specimen is received fresh, labeled with the patient's name,
medical
record number, and "right buttock mass." It consists of a 3978.0 g,
27.0 cm
medial to lateral, 20.0 cm anterior to posterior, and 18.0 cm superior
to
inferior oriented right buttock mass, which is partially surfaced by an
8.5
x 2.3 cm pink-tan, slightly wrinkled ellipse of skin. The skin surface
reveals an 8.5 cm in length healed scar, which is located 0.5 cm from
the
closest resection margin. The ellipse of skin is overlying the inferior
and
lateral margins. The external surface of the specimen is comprised of
brown-pink striated muscle and yellow lobulated adipose tissue. The
specimen is serially sectioned to reveal a well-circumscribed 20.0 x
16.0 x

[page 4 of 5]
14.0 cm tan-pink, slightly hemorrhagic, glistening and cystic mass that is

0.2 cm from the inferior margin, 0.3 cm from the posterior and superior margin, 0.4 cm from the anterior margin, 0.6 cm from the lateral margin,

1.0 cm from the medial margin, and 3.0 cm from the skin surface. The mass

also contains a focally necrotic area, which encompasses approximately 30%.

The remaining surrounding uninvolved soft tissue is comprised of red-brown

striated muscle and yellow lobulated and glistening adipose tissue. A portion of the viable mass is placed into , glutaraldehyde, and into

the -80 degree freezer pending further studies. Please note, digital images

are taken. Representative sections are submitted as follows:

Summary of sections: 7A, overlying skin with portion of scar, 1/1;

7B, soft tissue in relationship to tumor underlying the skin surface, 1/1;

7C, inferior margin in relationship to tumor, 1/1;

7D, posterior margin in relationship to tumor, 1/1;

7E, superior margin in relationship to tumor, 1/1;

7F, anterior margin in relationship to tumor, 1/1;

7G, lateral margin in relationship to tumor, 1/1;

7H, medial margin in relationship to tumor, 1/1;

7I-7O, representative sections of tumor, each 2/1;

7P, tumor in relationship to surrounding soft muscular tissue, 2/1.

Slides and report reviewed by Attending Pathologist.

SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Proximal Margin Right Buttock

FROZEN SECTION DIAGNOSIS:

1AFS: PROXIMAL MARGIN RIGHT BUTTOCK, BIOPSY: NEGATIVE FOR MALIGNANCY.

2) SOURCE: Proximal Nerve Margin Right Buttock

FROZEN SECTION DIAGNOSIS:

2AFS: PROXIMAL NERVE MARGIN, RIGHT BUTTOCK, BIOPSY: ATYPICAL CELLS PRESENT,
DEFER TO PERMANENT.

3) SOURCE: 3 o'clock Margin

FROZEN SECTION DIAGNOSIS:

3AFS: RIGHT BUTTOCK, 3 O'CLOCK MARGIN, EXCISION: NEGATIVE FOR MALIGNANCY.

4) SOURCE: 6 o'clock Margin

[page 5 of 5]
FROZEN SECTION DIAGNOSIS:

4AFS: RIGHT BUTTOCK, 6 O'CLOCK MARGIN, EXCISION: NEGATIVE FOR
MALIGNANCY.

5) SOURCE: 9 o'clock Margin

FROZEN SECTION DIAGNOSIS:

5AFS: RIGHT BUTTOCK, 9 O'CLOCK MARGIN, EXCISION: NEGATIVE FOR
MALIGNANCY.

6) SOURCE: 12 o'clock Margin

FROZEN SECTION DIAGNOSIS:

6AFS: RIGHT BUTTOCK, 12 O'CLOCK MARGIN, EXCISION: NEGATIVE FOR
MALIGNANCY.

IIIB/Aa Discrepancy		✓

Source: NCI Genomic Data Commons file c079e790-a96c-4f63-a5c3-14d66df41a49 (TCGA-VT-A80G.3074DB5D-53E6-49E4-A6A6-53C39F0FC6DB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).